Somatic mutation profile of cancer-model specimen HCM-CSHL-1262-C19-85M (3D Organoid; aliquot HCM-CSHL-1262-C19-85M-01D-A882-36), derived from the metastatic tumor of HCMI case HCM-CSHL-1262-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 65.4 years (23,884 days).
Specimen HCM-CSHL-1262-C19-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e6dafb2-a571-42d2-881f-ac0464cf6577.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-1262-C19-11A (Solid Tissue Normal), aliquot HCM-CSHL-1262-C19-11A-01D-A882-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f72e49b4-84c4-4c39-b88e-06d5f03f8113

The open-access MAF lists 208 somatic variants for this specimen: 141 protein-altering or splice-affecting, 56 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 56, Frame Shift Ins 4, Nonsense Mutation 4, 5'Flank 3, 5'UTR 2, RNA 2, Splice Site 2, Intron 2, 3'UTR 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS17 | c.1721+1G>A p.X574_splice | Splice Site (SNP) | VAF 285/287 reads (99%) | catalogued as rs749116256, CS097863; ClinVar: pathogenic; called by muse, mutect2
- DUSP16 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 248/388 reads (64%) | hotspot (GDC flag); catalogued as COSV53806110; called by muse, varscan2
- F11 | c.1481-1G>C p.X494_splice | Splice Site (SNP) | VAF 21/65 reads (32%) | catalogued as rs1057516506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3203dup p.N1068Kfs*5 | Frame Shift Ins (INS) | VAF 111/276 reads (40%) | catalogued as rs587776802; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.482C>A p.A161D | Missense Mutation (SNP) | VAF 189/651 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064795691, COSV52678014, COSV52747111, COSV52839912, COSV53772942; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A2ML1 | c.2361C>A p.F787L | Missense Mutation (SNP) | VAF 92/392 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs772150160; called by muse, mutect2, varscan2
- ABCA8 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 65/292 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs370110491; called by muse, mutect2, varscan2
- ADCY7 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 44/614 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs201627898, COSV54270739; called by muse, mutect2
- ADGRG4 | c.108dup p.G37Wfs*4 | Frame Shift Ins (INS) | VAF 144/148 reads (97%) | catalogued as rs1238901032; called by mutect2, varscan2
- APC | c.3493A>T p.K1165* | Nonsense Mutation (SNP) | VAF 90/148 reads (61%) | catalogued as COSV57326930, COSV57341138; called by muse, mutect2, varscan2
- ASIC4 | c.1109T>A p.I370N (on ENST00000347842 / NM_182847.3; = p.I389N on NM_018674.6) | Missense Mutation (SNP) | VAF 389/477 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99705223; called by muse, mutect2, varscan2
- CCDC85A | c.314T>A p.L105Q | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101339400; called by muse, mutect2, varscan2
- CHL1 | c.2634G>A p.M878I (on ENST00000397491 / NM_001253387.1; = p.M894I on NM_006614.4) | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.103); catalogued as COSV99851890; called by muse, mutect2, varscan2
- COLGALT2 | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 500/673 reads (74%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs534486400; called by muse, mutect2, varscan2
- CTNNA2 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 84/103 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs369970894; called by muse, varscan2
- CTSL | c.896A>T p.K299M | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58246737; called by muse, mutect2, varscan2
- DMRTB1 | c.363G>C p.E121D | Missense Mutation (SNP) | VAF 140/420 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs760118707; called by muse, mutect2, varscan2
- DNAH1 | c.2255G>A p.R752Q | Missense Mutation (SNP) | VAF 140/590 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs749446487, COSV70230279; called by muse, mutect2, varscan2
- DOCK8 | c.3868G>A p.A1290T | Missense Mutation (SNP) | VAF 125/267 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs932409929; called by muse, mutect2, varscan2
- DVL1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 411/568 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs767735434, COSV100229339; called by muse, mutect2, varscan2
- ETAA1 | c.1245A>T p.E415D | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs759198673; called by muse, mutect2, varscan2
- FGD5 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 317/608 reads (52%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs113314322; called by muse, mutect2, varscan2
- FOCAD | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 102/206 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.269); catalogued as rs375015668; called by muse, mutect2, varscan2
- FYB1 | c.1963G>A p.D655N (on ENST00000351578 / NM_199335.5; = p.D701N on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs932786216; called by muse, mutect2, varscan2
- FYB1 | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100685897; called by muse, mutect2, varscan2
- GPM6A | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 158/184 reads (86%) | SIFT tolerated (0.4); PolyPhen benign (0.122); catalogued as COSV99703150; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 122/554 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.187); catalogued as COSV100441254; called by muse, mutect2, varscan2
- HELZ2 | c.3208G>A p.A1070T (on ENST00000467148 / NM_001037335.2; = p.A501T on NM_033405.3) | Missense Mutation (SNP) | VAF 290/978 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV100915440; called by muse, mutect2, varscan2
- HTRA2 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 16/494 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1251760357, COSV51206123; called by muse, mutect2
- IGLON5 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 164/497 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs746860483; called by muse, mutect2, varscan2
- IWS1 | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 239/283 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99767384; called by muse, mutect2, varscan2
- KL | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 230/871 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs1482126606, COSV101199060; called by muse, mutect2, varscan2
- KRT31 | c.1097A>C p.N366T | Missense Mutation (SNP) | VAF 68/360 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs759839376; called by muse, mutect2, varscan2
- LAMA3 | c.7121G>A p.R2374Q (on ENST00000313654 / NM_198129.4; = p.R765Q on NM_000227.6) | Missense Mutation (SNP) | VAF 211/211 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs563440658, COSV52541866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LHX4 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 454/604 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374435549; called by muse, mutect2, varscan2
- LILRA2 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 398/618 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs764683666, COSV99253321; called by muse, varscan2
- MFSD4A | c.373G>C p.V125L | Missense Mutation (SNP) | VAF 486/684 reads (71%) | SIFT tolerated (0.24); PolyPhen benign (0.083); catalogued as COSV65656688; called by muse, varscan2
- OR2T29 | c.9C>A p.N3K | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs1274787430; called by muse, mutect2, varscan2
- PCDH11X | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 292/314 reads (93%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs377250651, COSV53454579; called by muse, mutect2, varscan2
- PCDHA10 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 269/532 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.135); catalogued as rs375062704, COSV56527999; called by muse, mutect2, varscan2
- PDZD2 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 118/199 reads (59%) | SIFT tolerated (0.74); PolyPhen benign (0.052); catalogued as rs368237088; called by muse, mutect2, varscan2
- PLEK | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 56/349 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as rs200352669, COSV52250616, COSV52252675; called by muse, mutect2, varscan2
- PPP4R3C | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 144/144 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1305786854; called by muse, mutect2, varscan2
- PUM3 | c.1253A>G p.K418R | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.313); catalogued as COSV67396268; called by muse, mutect2, varscan2
- RBP3 | c.2815A>G p.T939A | Missense Mutation (SNP) | VAF 125/592 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1206396792; called by muse, mutect2, varscan2
- RFWD3 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 239/429 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1445145229; called by muse, mutect2, varscan2
- RPGRIP1L | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV50904448, COSV50910437; called by muse, mutect2
- RPUSD2 | c.299A>G p.K100R | Missense Mutation (SNP) | VAF 126/408 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs1369086765; called by muse, mutect2, varscan2
- RYR1 | c.7105C>T p.R2369W | Missense Mutation (SNP) | VAF 481/762 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV62096336; called by muse, mutect2, varscan2
- SIX6 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 250/403 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1344962002, COSV59803126; called by muse, mutect2, varscan2
- TMEM132D | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 411/629 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs756539559, COSV70601435, COSV70624212; called by muse, mutect2, varscan2
- TOPAZ1 | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 75/323 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as COSV59070438; called by muse, mutect2, varscan2
- TSSK1B | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 160/383 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs374009361; called by muse, mutect2, varscan2
- TTN | c.24116G>A p.R8039H (on ENST00000591111; = p.R7112H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/150 reads (85%) | PolyPhen probably damaging (0.99); catalogued as rs376290076, COSV100624013; called by muse, mutect2, varscan2
- TUBA3C | c.260T>A p.F87Y | Missense Mutation (SNP) | VAF 137/488 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.115); catalogued as rs1204807947; called by muse, mutect2, varscan2
- UGT1A5 | c.220T>G p.F74V | Missense Mutation (SNP) | VAF 57/292 reads (20%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.85); catalogued as COSV100529395; called by muse, mutect2, varscan2
- ZNF521 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 127/234 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.205); catalogued as rs138180600; called by muse, mutect2, varscan2
- ZNF697 | c.1322A>G p.E441G | Missense Mutation (SNP) | VAF 154/1003 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as COSV70284097; called by muse, mutect2, varscan2
- ADGRB3 | c.1233G>C p.Q411H | Missense Mutation (SNP) | VAF 70/371 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRV1 | c.5383A>C p.N1795H | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK2 | c.5693A>T p.E1898V | Missense Mutation (SNP) | VAF 95/445 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- AL645922.1 | c.1111G>C p.D371H | Missense Mutation (SNP) | VAF 91/493 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALX4 | c.704A>C p.K235T | Missense Mutation (SNP) | VAF 100/534 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- ANK2 | c.1480G>T p.A494S | Missense Mutation (SNP) | VAF 124/143 reads (87%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- AQP9 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 72/225 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AREL1 | c.2335C>A p.P779T | Missense Mutation (SNP) | VAF 54/312 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- ARHGAP25 | c.1147T>C p.W383R (on ENST00000409202 / NM_001007231.3; = p.W375R on NM_014882.3) | Missense Mutation (SNP) | VAF 104/538 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARID1A | c.5655_5657delinsGG p.E1886Gfs*37 | Frame Shift Del (DEL) | VAF 175/587 reads (30%) | called by pindel, varscan2*
- CACNA1E | c.4837T>G p.L1613V | Missense Mutation (SNP) | VAF 82/510 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCDC83 | c.521A>G p.K174R | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.96); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC85A | c.313C>A p.L105M | Missense Mutation (SNP) | VAF 48/292 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP47 | c.2177C>A p.S726* | Nonsense Mutation (SNP) | VAF 57/114 reads (50%) | called by muse, mutect2, varscan2
- CHFR | c.713A>T p.K238M (on ENST00000432561 / NM_001161345.1; = p.K197M on NM_018223.2) | Missense Mutation (SNP) | VAF 101/440 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- CLEC20A | c.378G>T p.K126N | Missense Mutation (SNP) | VAF 259/381 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- COL6A3 | c.6308A>T p.K2103M | Missense Mutation (SNP) | VAF 73/402 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CRACR2A | c.1330A>C p.S444R | Missense Mutation (SNP) | VAF 112/474 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.714); called by muse, varscan2
- CUL1 | c.1404G>C p.K468N | Missense Mutation (SNP) | VAF 14/458 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.423); called by muse, mutect2
- DAOA | c.355T>C p.S119P | Missense Mutation (SNP) | VAF 60/463 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- DDX5 | c.216G>C p.E72D | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DEFB125 | c.316A>C p.K106Q | Missense Mutation (SNP) | VAF 109/666 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMRTA2 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.772); called by muse, varscan2
- DMWD | c.1391G>C p.G464A | Missense Mutation (SNP) | VAF 22/778 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.01); called by muse, mutect2
- ELFN1 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 24/906 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.094); called by muse, mutect2
- EPHB4 | c.1973G>A p.R658Q | Missense Mutation (SNP) | VAF 196/538 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EXOC3L1 | c.2055G>T p.L685F | Missense Mutation (SNP) | VAF 319/574 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- F13A1 | c.1605G>C p.K535N | Missense Mutation (SNP) | VAF 111/602 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FAM124A | c.746T>C p.L249P (on ENST00000322475 / NM_001242312.2; = p.L285P on NM_145019.4) | Missense Mutation (SNP) | VAF 121/722 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM216B | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 89/401 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAT3 | c.9764T>G p.V3255G | Missense Mutation (SNP) | VAF 66/352 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- FBLIM1 | c.25G>T p.V9L | Missense Mutation (SNP) | VAF 15/379 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2
- FBLN1 | c.95T>A p.L32H | Missense Mutation (SNP) | VAF 84/260 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- FLII | c.419A>C p.D140A | Missense Mutation (SNP) | VAF 89/251 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GATC | c.13T>G p.L5V | Missense Mutation (SNP) | VAF 137/369 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0); called by mutect2, varscan2
- GCNT7 | c.786C>G p.F262L | Missense Mutation (SNP) | VAF 116/772 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPR62 | c.154G>C p.A52P | Missense Mutation (SNP) | VAF 17/699 reads (2%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); called by muse, mutect2
- HECTD4 | c.12299A>T p.K4100M | Missense Mutation (SNP) | VAF 87/346 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- HIPK2 | c.3129T>G p.A1043= | Splice Region (SNP) | VAF 62/307 reads (20%) | called by muse, mutect2, varscan2
- IL12RB1 | c.1661G>T p.G554V | Missense Mutation (SNP) | VAF 225/350 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INHBC | c.17T>G p.L6R | Missense Mutation (SNP) | VAF 59/296 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- KCNH1 | c.1540G>C p.E514Q (on ENST00000271751 / NM_172362.3; = p.E487Q on NM_002238.4) | Missense Mutation (SNP) | VAF 131/715 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- KMT2A | c.9157A>C p.S3053R | Missense Mutation (SNP) | VAF 295/569 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LMNB1 | c.944G>C p.R315T | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- LRRN1 | c.1333C>A p.L445I | Missense Mutation (SNP) | VAF 121/484 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAN2A2 | c.1006T>C p.W336R | Missense Mutation (SNP) | VAF 181/181 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARCKS | c.665dup p.A223Gfs*119 | Frame Shift Ins (INS) | VAF 350/588 reads (60%) | called by mutect2, varscan2
- MICU1 | c.530A>C p.D177A | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- MSC | c.569C>G p.S190C | Missense Mutation (SNP) | VAF 68/446 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MXD1 | c.363G>C p.Q121H | Missense Mutation (SNP) | VAF 81/373 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- MYO1C | c.1370A>G p.E457G (on ENST00000648651 / NM_001080779.2; = p.E422G on NM_033375.5) | Missense Mutation (SNP) | VAF 84/908 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- NME8 | c.1113T>A p.F371L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- NOTCH4 | c.1285T>A p.C429S | Missense Mutation (SNP) | VAF 112/661 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR51A4 | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 168/395 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PDHA2 | c.82T>A p.S28T | Missense Mutation (SNP) | VAF 225/258 reads (87%) | SIFT tolerated (0.39); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PKD1 | c.4246T>C p.F1416L | Missense Mutation (SNP) | VAF 150/570 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- POU2F1 | c.560T>C p.L187P (on ENST00000541643 / NM_001365848.1; = p.L210P on NM_002697.4) | Missense Mutation (SNP) | VAF 96/499 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PPRC1 | c.1822G>C p.D608H | Missense Mutation (SNP) | VAF 172/551 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); called by muse, varscan2
- PRAM1 | c.1315C>G p.P439A | Missense Mutation (SNP) | VAF 24/819 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RANBP3 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 16/467 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2
- RELN | c.7858C>T p.P2620S | Missense Mutation (SNP) | VAF 84/316 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RFTN1 | c.1534G>C p.V512L | Missense Mutation (SNP) | VAF 260/494 reads (53%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGS13 | c.26G>T p.C9F | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.273); called by mutect2, varscan2
- RNF111 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 29/299 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- RRAD | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 20/624 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0.184); called by muse, mutect2
- SEC24C | c.2123C>T p.T708I | Missense Mutation (SNP) | VAF 191/696 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC22A1 | c.455A>C p.Q152P | Missense Mutation (SNP) | VAF 152/416 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- SLC38A1 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.012); called by muse, mutect2
- SLC52A1 | c.1308T>G p.F436L | Missense Mutation (SNP) | VAF 79/385 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC8A1 | c.2783G>A p.R928Q | Missense Mutation (SNP) | VAF 86/545 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPART | c.39T>G p.I13M | Missense Mutation (SNP) | VAF 39/316 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPATA31E1 | c.2744C>A p.T915N | Missense Mutation (SNP) | VAF 176/494 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- SPEG | c.7711T>G p.L2571V | Missense Mutation (SNP) | VAF 102/502 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.041); called by mutect2, varscan2
- TARS3 | c.1767G>C p.E589D | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TCF7L2 | c.1180G>A p.E394K (on ENST00000355995 / NM_001367943.1; = p.E371K on NM_030756.5) | Missense Mutation (SNP) | VAF 104/362 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- TENT5A | c.19T>C p.Y7H | Missense Mutation (SNP) | VAF 301/785 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM55 | c.27_28insG p.F10Vfs*10 | Frame Shift Ins (INS) | VAF 67/473 reads (14%) | called by mutect2, pindel, varscan2
- UBASH3A | c.120A>C p.K40N | Missense Mutation (SNP) | VAF 66/265 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDPCP | c.1930T>A p.L644M | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- ZC3H7B | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 21/476 reads (4%) | called by muse, mutect2
- ZCCHC7 | c.1158A>T p.E386D | Missense Mutation (SNP) | VAF 69/127 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFHX2 | c.1661T>A p.L554H | Missense Mutation (SNP) | VAF 95/523 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- ZNF428 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 162/536 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- A3GALT2 | c.942C>T p.S314= | Silent (SNP) | VAF 219/418 reads (52%) | catalogued as rs777814427; called by muse, mutect2, varscan2
- ABI3 | c.375C>T p.I125= | Silent (SNP) | VAF 176/636 reads (28%) | catalogued as rs748149316; called by muse, varscan2
- ADORA1 | c.828C>T p.L276= | Silent (SNP) | VAF 46/920 reads (5%) | called by muse, mutect2
- ATP13A4 | c.1209G>C p.L403= | Silent (SNP) | VAF 84/439 reads (19%) | catalogued as rs368640670; called by muse, mutect2, varscan2
- BCAS1 | c.228C>T p.N76= | Silent (SNP) | VAF 104/848 reads (12%) | catalogued as rs778133024, COSV65086291; called by muse, mutect2, varscan2
- C6orf118 | c.114G>T p.L38= | Silent (SNP) | VAF 295/520 reads (57%) | called by muse, mutect2, varscan2
- CDC25A | c.702C>T p.P234= | Silent (SNP) | VAF 66/403 reads (16%) | called by muse, mutect2, varscan2
- CLCN1 | c.1113A>G p.Q371= | Silent (SNP) | VAF 79/460 reads (17%) | called by muse, mutect2, varscan2
- DCDC1 | c.1704G>A p.S568= | Silent (SNP) | VAF 150/318 reads (47%) | catalogued as rs890487026; called by muse, varscan2
- DCT | c.1131C>T p.N377= | Silent (SNP) | VAF 135/538 reads (25%) | catalogued as rs776819456, COSV65468614; called by muse, mutect2, varscan2
- DGKG | c.1137A>G p.L379= | Silent (SNP) | VAF 47/303 reads (16%) | called by muse, mutect2, varscan2
- DISP1 | c.3189T>A p.A1063= | Silent (SNP) | VAF 71/669 reads (11%) | called by muse, mutect2, varscan2
- DRD5 | c.150C>G p.L50= | Silent (SNP) | VAF 122/378 reads (32%) | called by muse, mutect2, varscan2
- EFEMP1 | c.1260C>T p.A420= | Silent (SNP) | VAF 33/324 reads (10%) | called by muse, mutect2, varscan2
- FAT4 | c.11916A>T p.G3972= | Silent (SNP) | VAF 77/92 reads (84%) | called by muse, varscan2
- FREM2 | c.2487A>T p.P829= | Silent (SNP) | VAF 123/593 reads (21%) | called by muse, mutect2, varscan2
- GPR137 | c.561G>A p.A187= | Silent (SNP) | VAF 218/558 reads (39%) | catalogued as rs1426704752; called by muse, mutect2, varscan2
- GPR45 | c.585C>T p.Y195= | Silent (SNP) | VAF 490/613 reads (80%) | catalogued as rs767278498, COSV51524986, COSV99307234; called by muse, mutect2, varscan2
- HHIPL2 | c.351C>T p.Y117= | Silent (SNP) | VAF 293/392 reads (75%) | catalogued as rs1291388394, COSV58563595; called by muse, mutect2, varscan2
- HRH3 | c.144G>C p.T48= | Silent (SNP) | VAF 108/841 reads (13%) | catalogued as rs763526881; called by muse, varscan2
- IER2 | c.171C>A p.P57= | Silent (SNP) | VAF 132/598 reads (22%) | called by muse, mutect2, varscan2
- IQCN | c.1263G>A p.A421= | Silent (SNP) | VAF 114/535 reads (21%) | catalogued as rs377121664; called by muse, mutect2, varscan2
- IQSEC3 | c.3351T>A p.A1117= | Silent (SNP) | VAF 103/507 reads (20%) | called by muse, mutect2, varscan2
- KDM4F | c.291G>A p.Q97= | Silent (SNP) | VAF 226/538 reads (42%) | called by muse, mutect2, varscan2
- KRR1 | c.339C>T p.I113= | Silent (SNP) | VAF 71/326 reads (22%) | called by muse, mutect2, varscan2
- KRT14 | c.123C>T p.R41= | Silent (SNP) | VAF 547/770 reads (71%) | catalogued as rs547482686; called by muse, mutect2, varscan2
- MCF2L2 | c.2316C>T p.F772= | Silent (SNP) | VAF 65/314 reads (21%) | catalogued as rs200679619, COSV61053428; called by muse, mutect2, varscan2
- MUC3A | c.8451C>T p.T2817= | Silent (SNP) | VAF 119/538 reads (22%) | catalogued as rs912845282; called by muse, mutect2, varscan2
- MYOM1 | c.4446T>C p.T1482= | Silent (SNP) | VAF 68/235 reads (29%) | called by muse, mutect2, varscan2
- OR52N1 | c.909A>G p.R303= | Silent (SNP) | VAF 71/362 reads (20%) | called by muse, mutect2, varscan2
- OR5D3P | c.120C>T p.F40= | Silent (SNP) | VAF 118/328 reads (36%) | called by muse, mutect2, varscan2
- P2RX6 | c.738C>T p.L246= | Silent (SNP) | VAF 301/302 reads (100%) | catalogued as rs1432870194, COSV60385424; called by muse, mutect2, varscan2
- PAF1 | c.9C>T p.P3= | Silent (SNP) | VAF 119/583 reads (20%) | called by muse, mutect2, varscan2
- PCDHA6 | c.1677C>T p.N559= | Silent (SNP) | VAF 267/490 reads (54%) | catalogued as rs576399974; called by muse, mutect2, varscan2
- PCDHA8 | c.2031A>G p.K677= | Silent (SNP) | VAF 130/385 reads (34%) | catalogued as rs374155064; called by muse, mutect2, varscan2
- PCDHB12 | c.1383C>T p.R461= | Silent (SNP) | VAF 225/520 reads (43%) | catalogued as COSV53393177; called by muse, mutect2, varscan2
- PDZD8 | c.834C>T p.I278= | Silent (SNP) | VAF 14/432 reads (3%) | called by muse, mutect2
- PIP5KL1 | c.636C>A p.G212= (on ENST00000388747 / NM_001135219.2; = p.G9= on NM_173492.1) | Silent (SNP) | VAF 19/724 reads (3%) | called by muse, mutect2
- PKD2L1 | c.1587C>T p.I529= | Silent (SNP) | VAF 118/402 reads (29%) | catalogued as rs1286609913, COSV58399406; called by muse, mutect2, varscan2
- PLEKHB2 | c.810C>A p.R270= | Silent (SNP) | VAF 96/415 reads (23%) | called by muse, mutect2, varscan2
- PLXNC1 | c.1464A>G p.V488= | Silent (SNP) | VAF 101/150 reads (67%) | catalogued as COSV51574261; called by muse, mutect2, varscan2
- RBM19 | c.1422C>T p.H474= | Silent (SNP) | VAF 77/264 reads (29%) | catalogued as rs745398765; called by muse, mutect2, varscan2
- RTKN2 | c.1459C>T p.L487= | Silent (SNP) | VAF 208/330 reads (63%) | called by muse, mutect2, varscan2
- SAMD4A | c.1410G>C p.G470= | Silent (SNP) | VAF 423/673 reads (63%) | catalogued as rs747712759, COSV51885334; called by muse, mutect2, varscan2
- SCN10A | c.5136C>T p.I1712= | Silent (SNP) | VAF 60/427 reads (14%) | catalogued as rs757792173, COSV71860724, COSV71862422; called by muse, mutect2, varscan2
- SETDB1 | c.2049T>G p.T683= | Silent (SNP) | VAF 94/563 reads (17%) | called by muse, mutect2, varscan2
- SIRT5 | c.801G>A p.R267= | Silent (SNP) | VAF 236/443 reads (53%) | called by muse, mutect2, varscan2
- SYNDIG1 | c.534G>A p.P178= | Silent (SNP) | VAF 291/940 reads (31%) | catalogued as rs536225349, COSV100965456, COSV65233168; called by muse, mutect2, varscan2
- TBC1D10B | c.93G>T p.G31= | Silent (SNP) | VAF 325/783 reads (42%) | called by muse, mutect2, varscan2
- TEAD3 | c.582G>A p.P194= | Silent (SNP) | VAF 173/428 reads (40%) | catalogued as rs758203896; called by muse, mutect2, varscan2
- TECTA | c.4878C>T p.N1626= | Silent (SNP) | VAF 224/440 reads (51%) | catalogued as rs151056317; called by muse, mutect2, varscan2
- TMEM94 | c.1644G>A p.V548= | Silent (SNP) | VAF 132/346 reads (38%) | called by muse, mutect2, varscan2
- TTN | c.63718C>A p.R21240= (on ENST00000591111; = p.R13816= on NM_003319.4) | Silent (SNP) | VAF 148/313 reads (47%) | catalogued as COSV100620224; called by muse, mutect2, varscan2
- YWHAE | c.174C>T p.A58= | Silent (SNP) | VAF 52/896 reads (6%) | catalogued as rs766740530; called by muse, mutect2
- ZBTB39 | c.1854C>T p.S618= | Silent (SNP) | VAF 115/455 reads (25%) | called by muse, mutect2, varscan2
- ZNF541 | c.2841C>T p.S947= | Silent (SNP) | VAF 110/536 reads (21%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840786 G>A | 5'Flank (SNP) | VAF 99/888 reads (11%) | catalogued as rs79709641, COSV58332916; called by muse, varscan2
- AL132655.6 | chr20:58840790 C>T | 5'Flank (SNP) | VAF 104/866 reads (12%) | catalogued as COSV58332560; called by muse, varscan2
- C2orf16 | chr2:27576146 G>A | 5'Flank (SNP) | VAF 253/298 reads (85%) | catalogued as rs538908364, COSV101284453; called by muse, mutect2, varscan2
- FAM174B | c.*85T>C | 3'UTR (SNP) | VAF 92/252 reads (37%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+5814G>C | Intron (SNP) | VAF 85/448 reads (19%) | called by muse, mutect2, varscan2
- KLHL1 | c.-307G>T | 5'UTR (SNP) | VAF 34/558 reads (6%) | called by muse, mutect2
- PRSS40A | n.230C>T | RNA (SNP) | VAF 188/454 reads (41%) | catalogued as rs1397339383; called by muse, varscan2
- REXO1L1P | n.1506G>A | RNA (SNP) | VAF 130/1876 reads (7%) | catalogued as rs1448634678; called by muse, mutect2
- SCNN1D | c.-316C>T | 5'UTR (SNP) | VAF 113/689 reads (16%) | called by muse, mutect2, varscan2
- SPATA13 | c.-222-25455G>A | Intron (SNP) | VAF 197/809 reads (24%) | catalogued as rs1001090536; called by muse, mutect2, varscan2
- TSEN34 | c.*292G>C | 3'UTR (SNP) | VAF 21/436 reads (5%) | called by muse, mutect2
